Gene-level copy-number profile of tumor specimen ALCH-B2VL-TTP1-A from ALCHEMIST case ALCH-B2VL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Pleomorphic carcinoma; Age at diagnosis: 65.8 years (24,051 days).
Specimen ALCH-B2VL-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a49d0306-cfe1-4302-8564-b806bc477547.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2VL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/8223d0fe-2c4b-488b-b4c7-da4924f0e9f1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 9,281; copy number 2: 44,835; copy number 3: 3,165; copy number 4: 970; copy number 6: 5; copy number 8: 38; copy number 9: 63; copy number 10: 63; copy number 11: 91; copy number 12: 10; copy number 13: 77; copy number 14: 1; copy number 15: 118; copy number 16: 40; copy number 17: 29; copy number 18: 69.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,974,502–17,011,928, 5 genes: MFAP2, AL049569.2, AL049569.1, ATP13A2, AL049569.3.
- chr2:72,129,238–72,148,038, 1 gene: CYP26B1.
- chr6:149,446,795–149,485,014, 1 gene: ZC3H12D.
- chr7:102,194,076–102,264,979, 2 genes (within-gene range 0–2): AC005086.1, AC005088.1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:21,278,050–22,128,103, 36 genes (within-gene range 0–1): IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:125,372,325–125,417,586, 2 genes: AL627223.1, Metazoa_SRP.
- chr17:7,646,627–7,657,770, 1 gene: ATP1B2.
- chr17:15,761,614–15,793,045, 9 genes: AC005324.1, CDRT15P2, ZSWIM5P1, RNA5SP436, IL6STP1, MEIS3P1, AC015922.2, AC015922.3, AC015922.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 604 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:20,782,279–24,445,128, 60 genes, copy number 15: SP8, RPL23P8, LINC01162, RPS26P30, AC080068.1, RN7SL542P, ASS1P11, RNU1-15P, AC005094.1, SP4, MIR1183, DNAH11, CDCA7L, RAPGEF5, RNA5SP227, STEAP1B, EEF1A1P6, AC002480.1, AC002480.2, IL6-AS1, IL6, MTCYBP42, AC073072.1, TOMM7, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A, KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3, TPT1P7, AC003087.1, RNA5SP228, AC004485.1, NPY, AC003044.1.
- chr7:29,514,224–34,871,582, 92 genes, copy number 12–18 (within-gene range 4–18) (broad region; genes not listed).
- chr7:38,178,245–38,378,804, 25 genes, copy number 17: STARD3NL, TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr7:67,691,058–68,319,676, 8 genes, copy number 10–13: AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3.
- chr7:71,779,491–73,624,543, 51 genes, copy number 9: CALN1, RNA5SP232, AC005011.1, ABCF2P2, TYW1B, MIR4650-2, AC211469.2, AC211469.1, RN7SL377P, SBDSP1, RN7SL625P, SPDYE7P, POM121, AC211476.2, NSUN5P2, TRIM74, STAG3L3, AC211476.1, Y_RNA, PMS2P7, Y_RNA, SPDYE8, PMS2P8, Y_RNA, AC211476.5, AC211476.3, SPDYE11, AC211476.4, Y_RNA, SPDYE9, PMS2P6, Y_RNA, SPDYE10P, GTF2IP4, PHBP5, NCF1B, GTF2IRD2P1, POM121B, NSUN5, TRIM50, AC211485.1, FKBP6, RNU6-1080P, Y_RNA, FZD9, BAZ1B, RNU6-1198P, BCL7B, TBL2, MLXIPL, AC005089.1.
- chr7:74,906,673–76,087,547, 46 genes, copy number 10: SPDYE12P, CASTOR2, RCC1L, Metazoa_SRP, GTF2IRD2B, NCF1C, GTF2IP1, PHBP6, AC211486.5, AC211486.2, AC211486.4, SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA, SPDYE15, PMS2P2, Y_RNA, STAG3L1, Y_RNA, AC211486.1, TRIM73, NSUN5P1, POM121C, AC211429.1, SPDYE5, PMS2P3, Y_RNA, HIP1, AC004491.1, CCL26, CCL24, AC005102.1, RHBDD2, POR, MIR4651, RPL7L1P3, SNORA14A, TMEM120A, STYXL1, AC006330.1, MDH2, AC005077.4, RNU6-863P.
- chr7:81,175,508–83,664,625, 19 genes, copy number 9–10 (within-gene range 9–17): AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2.
- chr7:85,636,013–86,864,884, 5 genes, copy number 11–14: AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1.
- chr11:64,291,302–64,316,743, 5 genes, copy number 6 (within-gene range 2–6): KCNK4, KCNK4-TEX40, Y_RNA, CATSPERZ, ESRRA.
- chr12:31,382,226–31,591,136, 1 gene, copy number 15 (within-gene range 3–15): DENND5B.
- chr12:31,465,062–32,896,777, 50 genes, copy number 15: AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2, Y_RNA, FGD4, RNU6-494P, DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2, PKP2, AC087588.1, RPL35AP27.
- chr12:40,196,744–41,072,415, 7 genes, copy number 9 (within-gene range 1–9): LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1.
- chr12:43,835,967–44,389,762, 4 genes, copy number 8: TMEM117, ZNF75BP, AC025030.2, AC025030.1.
- chr12:53,739,611–55,030,017, 68 genes, copy number 13–16 (broad region; genes not listed).
- chr12:61,231,159–65,491,430, 89 genes, copy number 8–17 (within-gene range 3–25) (broad region; genes not listed).
- chr12:67,440,998–70,243,379, 66 genes, copy number 11–13 (within-gene range 3–13) (broad region; genes not listed).
- chr12:70,239,114–70,242,430, 1 gene, copy number 11: AC092881.2.
- chr12:88,049,016–88,142,099, 1 gene, copy number 11 (within-gene range 1–11): CEP290.
- chr12:88,142,296–88,602,195, 6 genes, copy number 11: TMTC3, Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1.

Autosomal genes at a single copy (total copy number 1): 6,428. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
